Somatic mutation profile of tumor specimen 0DRGEW from CCDI case PBCACX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, anaplastic; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.4 years (1,985 days).
Specimen 0DRGEW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afdb6a6a-65b6-4c7c-844f-fec221f7f556.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRGED (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6db0022e-e073-40e9-bf3c-ba574323388d

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WDPCP | c.1825C>T p.L609F | Missense Mutation (SNP) | VAF 148/1518 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV55425040; called by muse, mutect2
- DKC1 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 373/1105 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGB1 | c.1536G>A p.A512= | Silent (SNP) | VAF 22/790 reads (3%) | called by muse, mutect2
- RHAG | c.1212+52A>T | Intron (SNP) | VAF 15/428 reads (4%) | called by muse, mutect2
- RIMBP2 | c.2361+81C>T | Intron (SNP) | VAF 7/142 reads (5%) | catalogued as rs949033648; called by muse, mutect2
